Gene-level copy-number profile of tumor specimen TCGA-FG-5963-01A from TCGA case TCGA-FG-5963, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 23.5 years (8,571 days).
Specimen TCGA-FG-5963-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.9d6bf5f9-e72a-48da-a8c5-9268309275ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-5963-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8825ef8a-a14d-44d1-89f0-54690bd6563b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 172; copy number 1: 14,918; copy number 2: 43,801; copy number 3: 835; copy number 4: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-5963-01A-11D-1704-01): tumor purity 0.42, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 163 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:72,996,803–77,811,844, 58 genes (within-gene range 0–1): PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P.
- chr3:78,525,101–79,767,998, 4 genes (within-gene range 0–1): MRPS17P3, ROBO1, AC055731.1, RN7SL751P.
- chr9:20,331,446–27,066,134, 101 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
